CCDI case PBBUWZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/80144707-c3dd-4b3c-a7d1-95cc576901ee

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Craniopharyngioma: ICD-O-3 morphology code: 9350/1; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 8.5 years (3,088 days).

Biospecimens (3 samples)
- Sample 0DHOGZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHOJ2: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHOJ9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
